Gene-level copy-number profile of tumor specimen TCGA-DS-A1OB-01A from TCGA case TCGA-DS-A1OB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 45.7 years (16,685 days).
Specimen TCGA-DS-A1OB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.94181794-80b4-4aab-b3c9-37d9d5825a84.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DS-A1OB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/8cd870bd-27d2-422b-821c-50a067ded98c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,394; copy number 2: 20,084; copy number 3: 14,193; copy number 4: 17,930; copy number 5: 3,196; copy number 7: 3,014; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:74,344,550–74,372,416, 2 genes: TIMM9P1, RPSAP6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,212 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr4:77,216,416–77,312,111, 2 genes, copy number 8: AC008638.3, AC008638.2.
- chr7:70,972–159,233,377, 3,014 genes, copy number 7 (broad region; genes not listed).
- chr9:14,475–10,612,723, 147 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr17:10,258,762–22,205,154, 445 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
